CCDI case PBCIRI — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Gliomas; Primary site: Eye and adnexa.
https://portal.gdc.cancer.gov/cases/8976cb38-4695-4be7-bb59-49a565e4a6ec

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Ganglioglioma, NOS: ICD-O-3 morphology code: 9505/1; Tissue or organ of origin: Orbit, NOS; Age at diagnosis: 0.1 years (19 days).

Biospecimens (3 samples)
- Sample 0DSTY2: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DSTY8: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DSTYH: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
